Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABA, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABA-01A (Primary Tumor).

[page 1 of 4]
Surgery date: Surgical Pathology

ICD-03

DIAGNOSIS:

A. Lymph nodes, common hepatic artery #1, excision: A single (1) lymph node is negative for tumor.

B. Lymph nodes, common hepatic artery #2, excision: Fibroadipose tissue with chronic inflammation.

C. Soft tissue, pancreatic portal vein interface, excision: Fibrous tissue with granulation tissue and acute inflammation.

D. Pancreas, neck margin, excision: Negative for tumor.

E. Head of pancreas, gallbladder, duodenum, and portion of jejunum; Whipple resection: Invasive moderately differentiated ductal adenocarcinoma is identified forming a solid mass (4.3 x 3.5 x 3.1 cm) located in the pancreatic head. The tumor extends beyond the pancreas to involve the peripancreatic soft tissue, duodenal wall, and bile duct. Both angiolymphatic and perineural invasion are absent. Tumor necrosis is absent. The uncinate margin is positive for invasive carcinoma whereas the portal vein groove and cystic duct margins are negative. The adjacent non-neoplastic pancreatic parenchyma shows marked chronic pancreatitis. A single (1) cystic duct lymph node is negative for tumor. The gallbladder demonstrate chronic cholecystitis. Multiple (2 of 10) regional lymph nodes are positive for metastatic adenocarcinoma.

F. Lymph nodes, peripancreatic, excision: Multiple (2) lymph nodes are negative for tumor.

G. Lymph nodes, gastroduodenal, excision: Multiple (5) lymph nodes are negative for tumor.

H. Lymph nodes, celiac axis, excision: Multiple (2) lymph nodes are negative for tumor.

With available surgical material, [AJCC pT3N1] (7th edition, 2010).

This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

Adenocarcinoma duct NOS
850013
Site Pancreas head C25.0
JW 5/5/14

Interpreted by:

[page 2 of 4]
Report electronically signed by
Transcribed by:

GROSS DESCRIPTION:

- A. Received fresh labeled "common hepatic artery lymph nodes" is a 2.5 x 2.5 x 0.5 cm aggregate of adipose and lymphatic tissue. All submitted. Grossed by
- B. Received fresh labeled "common hepatic artery lymph node #2" is a 2.5 x 2.1 x 0.7 cm aggregate of adipose tissue, lymphatic tissue not identified grossly. All submitted. Grossed by
- C. Received fresh labeled "pancreatic portal vein interface" is a 0.7 x 0.6 x 0.2 cm portion of tan-pink tissue. All submitted. Grossed by
- D. Received fresh labeled "pancreatic neck margin" is a 3.0 x 2.1 x 0.8 cm portion of pancreatic tissue with orientation. All submitted. Grossed by
- E. Received fresh labeled "head of pancreas, gallbladder, duodenum, portion of jejunum, and pancreas stones" is a Whipple specimen consisting of 34.0 cm in length portion of duodenum, 7.0 x 5.2 x 4.8 cm portion of pancreas, and a 16.5 x 5.5 x 2.4 cm gallbladder. The pancreatic uncinate margin is inked yellow and shaved. The portal vein groove is inked blue and submitted perpendicularly. There is a 4.3 x 3.5 x 3.1 cm annular and diffusely infiltrative mass within the pancreas at the uncinate margin. The mass extends to peripancreatic soft tissue. A stent is present within the common bile duct. Multiple irregular fragmented stones are identified within the pancreas and pancreatic duct system, showing obstruction toward the ampulla and dilation toward the pancreatic neck margin. The gallbladder contains no choleliths. Peripancreatic lymph nodes are identified. Representative sections are submitted. Grossed by
- F. Received fresh labeled "peripancreatic lymph nodes" is a 2.9 x 2.2 x 0.8 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted. Grossed by
- G. Received fresh labeled "gastrocolic lymph nodes" is a 6.7 x 2.5 x 0.7 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted. Grossed by
- H. Received fresh labeled "celiac axis lymph nodes" is a 2.9 x 1.0 x 0.8 cm aggregate of adipose and lymphatic tissue. Lymph nodes

[page 3 of 4]
submitted. Grossed by

BLOCK SUMMARY:

Part A: Common hepatic artery lymph node

- 1 Comm hepatic artery LN 1(A1)
- 2 Comm hepatic artery LN 1(A2)

Part B: Common hepatic artery lymph node #2

- 1 Common hepat artery LN#2(B1)
- 2 Common hepat artery LN#2(B2)

Part C: Pancreatic portal vein interface

- 1 Pancreatic portal vein

Part D: Pancreatic neck margin

- 1 Pancreatic neck margin 1
- 2 Pancreatic neck margin 2

Part E: Head of pancreas, gallbladder, duodenum, portion jejunum, and pancreas stone

- 1 Uncinate margin 1
- 2 Uncinate margin 2
- 3 Uncinate margin 3
- 4 Uncinate margin 4
- 5 Bile duct margin
- 6 Portal vein groove margin
- 7 Ampulla
- 8 Pancreatic duct
- 9 Pancreatic duct
- 10 Peripancreatic LN 1of5(E1)
- 11 Peripancreatic LN 2of5(E1)
- 12 Peripancreatic LN 3of5(E1)
- 13 Peripancreatic LN 4of5(E1)
- 14 Peripancreatic LN 5of5(E1)
- 15 Peripancreatic LN 4(E2)
- 16 Peripancreatic LN 7(E3)
- 17 Cystic duct LN 1(E4)
- 18 Gallbladder
- 19 Peripancreatic LN 2(E5)
- 20 Pancreatic mass
- 21 Pancreatic mass

Part F: Peripancreatic lymph nodes

- 1 Peripancreatic LN 2 (F1)
- 2 Peripancreatic LN 2 (F2)

Part G: Gastro colic lymph nodes

- 1 Gastro colic LN 4(G1)
- 2 Gastro colic LN 2(G2)

[page 4 of 4]
Part H: Celiac axis lymph nodes
1 Celiac axis LN 2(H1)

BTM	1/6/14	

Source: NCI Genomic Data Commons file 31a7998b-2d23-4089-bd4a-e1aafaa19892 (TCGA-2J-AABA.FA359088-C46F-4395-9AFA-4B539C3ACF76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).